Surgical pathology report (de-identified scan), TCGA case TCGA-05-4405, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Indivumed, specimen TCGA-05-4405-01A (Primary Tumor).

Main diagnosis/diagnoses:

Peripheral bronchopulmonary, histologically mixed adenocarcinoma of the right lower lobe of the lung with acinar and papillary components, located in S8.

TNM classification pT2 pN0 V1 R0, stage IB

C 34.1 M 8255/3

Comment/supplementary remark:

The tumor has infiltrated blood vessels in the tumor. The visceral pleura, the resection margin of bronchi and vessels and all the lymph nodes removed and identified are tumor-free.

ICD-O-3

Adenocarcinoma, w/ mixed subtypes
8255/3

Site: lung, (R) lower lobe C 34.3

fw
2/17/14

Source: NCI Genomic Data Commons file 17e0add1-4788-493a-817c-adaa6f018072 (TCGA-05-4405.AB2C32B2-3CB1-4977-8C79-7B19F9022DFB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).